Gene-level copy-number profile of tumor specimen TCGA-2J-AABO-01A from TCGA case TCGA-2J-AABO, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 43.4 years (15,869 days).
Specimen TCGA-2J-AABO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.09dce8f4-4c36-4223-b8b4-2d4be3b2314d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2J-AABO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4eb9dead-8c54-4caa-99be-a39878a31a20

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,032; copy number 2: 9,854; copy number 3: 18,963; copy number 4: 24,017; copy number 5: 2,791; copy number 6: 2,101; copy number 7: 318; copy number 8: 211; copy number 9: 244; copy number 10: 33; copy number 11: 28; copy number 13: 3; copy number 14: 37; copy number 24: 56; copy number 30: 35; copy number 31: 24; copy number 35: 24; copy number 41: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2J-AABO-01A-21D-A40V-01): tumor purity 0.26, ploidy 3.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 527 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:115,048,011–118,264,489, 70 genes, copy number 13–41 (within-gene range 3–41) (broad region; genes not listed).
- chr3:103,159,960–107,348,464, 31 genes, copy number 10 (within-gene range 6–10): RNU1-43P, NDUFA4P2, MIR548AB, AC046144.1, TUBBP11, RAP1BP2, AC091804.1, ALCAM, CBLB, AC131237.1, AC079382.1, AC079382.2, LINC00882, Y_RNA, AC080097.1, Y_RNA, FCF1P3, MTND4P16, MTND4LP3, MTND3P6, MTCO3P35, MTATP6P22, MTND5P16, MTND6P6, MTCO1P35, MTND1P16, MTND2P14, RNU6-1308P, AC117435.1, AC074043.1, DUBR.
- chr3:107,327,830–107,329,962, 2 genes, copy number 10: CSP2, AC063944.2.
- chr19:29,448,038–38,208,369, 307 genes, copy number 9–30 (within-gene range 7–30) (broad region; genes not listed).
- chr19:39,328,353–39,607,474, 24 genes, copy number 35: GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16, SUPT5H, TIMM50, DLL3, SELENOV, EID2B, AC011500.3, TDGF1P7, EID2, AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13.
- chr19:39,984,134–41,027,720, 56 genes, copy number 24 (within-gene range 6–24): ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796, HIPK4, PRX, SERTAD1, AC010271.2, SERTAD3, AC010271.1, BLVRB, Metazoa_SRP, SPTBN4, SHKBP1, LTBP4, NUMBL, COQ8B, RNU6-195P, ITPKC, C19orf54, SNRPA, MIA, MIA-RAB4B, RAB4B, RAB4B-EGLN2, AC008537.4, EGLN2, AC008537.1, CYP2T1P, CYP2F2P, AC008537.2, AC008537.3, CYP2A6, CYP2A7, CYP2G1P, CYP2A7P2, CYP2B7P, AC092071.1, CYP2B6, CYP2A7P1.
- chr20:87,250–1,329,139, 36 genes, copy number 14: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4, RSPO4, AL110114.1, PSMF1, ACTG1P3, TMEM74B, AL031665.1, C20orf202, RAD21L1, SNPH, SDCBP2.
- chr20:1,320,710–1,324,367, 1 gene, copy number 14: AL136531.3.

Autosomal genes at a single copy (total copy number 1): 1,032. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
